Gene-level copy-number profile of tumor specimen TCGA-69-7980-01A from TCGA case TCGA-69-7980, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage I; Age at diagnosis: 70.0 years (25,583 days).
Specimen TCGA-69-7980-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.1c3f238c-281d-4821-b6af-01bc114d9f39.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-69-7980-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4fadcd12-7e26-4b83-ad3a-4fb265c5db1e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 115; copy number 1: 494; copy number 2: 8,305; copy number 3: 20,018; copy number 4: 13,154; copy number 5: 15,334; copy number 6: 1,325; copy number 7: 77; copy number 8: 443; copy number 9: 42; copy number 10: 111; copy number 11: 9; copy number 12: 2; copy number 13: 376; copy number 16: 6; copy number 20: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-69-7980-01A-11D-2183-01): tumor purity 0.55, ploidy 3.76, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 115 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,341,669–20,622,499, 1 gene (within-gene range 0–2): MLLT3.
- chr9:20,502,265–23,438,700, 66 genes (within-gene range 0–3) (broad region; genes not listed).
- chr14:76,279,173–77,498,816, 47 genes: AC016526.3, AC016526.1, ESRRB, AC008050.1, CYCSP1, RPSAP3, AC007376.1, AC007376.2, VASH1, AF111169.3, AF111169.1, VASH1-AS1, ANGEL1, AF111169.4, LRRC74A, RPL22P2, RN7SKP17, AF111169.2, AC007686.4, LINC01629, RN7SL356P, AC007686.1, IRF2BPL, AC007686.3, LINC02288, AC007686.2, LINC02289, AC007686.5, CIPC, AC007375.2, TMEM63C, ZDHHC22, AC007375.3, FAM204DP, AC007375.1, NGB, MIR1260A, POMT2, GSTZ1, TMED8, AC007954.1, SAMD15, NOXRED1, VIPAS39, AHSA1, AF111168.1, ISM2.
- chr14:77,547,566–77,547,846, 1 gene: RN7SL587P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,068 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:166,387,727–169,485,944, 75 genes, copy number 7 (broad region; genes not listed).
- chr3:88,601,061–89,048,434, 3 genes, copy number 11–20: NDUFA5P5, ICE2P2, GAPDHP50.
- chr3:89,587,886–90,184,733, 4 genes, copy number 11–12: MTCO2P6, MTCO1P6, U3, RNU6-712P.
- chr4:43,972,921–52,097,299, 85 genes, copy number 10 (broad region; genes not listed).
- chr4:56,907,876–59,180,414, 27 genes, copy number 10–16 (within-gene range 5–16): REST, AC069307.1, NOA1, POLR2B, RNU6-998P, IGFBP7, UBE2CP3, IGFBP7-AS1, AC111197.1, AC105390.1, RPS26P24, LINC02380, AC013724.1, AC107396.1, AC093725.2, AC093725.1, AC104790.1, SRIP1, AC096725.1, LINC02494, AC019133.1, AC017091.1, LINC02619, LINC02429, AC097501.1, AC108517.2, AC108517.1.
- chr6:35,797,206–42,050,357, 146 genes, copy number 8–11 (within-gene range 5–11) (broad region; genes not listed).
- chr7:27,830,573–28,180,795, 2 genes, copy number 7 (within-gene range 3–7): JAZF1, AC004549.1.
- chr9:6,720,863–7,175,648, 1 gene, copy number 9 (within-gene range 5–9): KDM4C.
- chr9:6,834,456–10,632,203, 22 genes, copy number 9: ACTG1P14, AL513412.1, AL161443.1, AL157703.1, RPL4P5, PPIAP33, AL354694.1, DMAC1, AL135923.2, AL135923.1, PTPRD, AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3, RN7SL5P, AL513422.1, AL135790.2, PTPRD-AS2, AL135790.1.
- chr9:31,165,618–31,506,615, 5 genes, copy number 10: AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30.
- chr12:53,046,969–59,789,855, 322 genes, copy number 8–9 (within-gene range 5–9) (broad region; genes not listed).
- chr18:47,390–15,330,282, 376 genes, copy number 13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 494. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
